Gene-level copy-number profile of tumor specimen TCGA-DX-A3LS-01A from TCGA case TCGA-DX-A3LS, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 78.4 years (28,649 days).
Specimen TCGA-DX-A3LS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.0bce492e-f15f-4fb4-b88b-0a32887bdc49.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A3LS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f15eee61-3308-4200-a7e5-6091e6506b18

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,534; copy number 2: 40,945; copy number 3: 3,119; copy number 4: 1,164; copy number 5: 160; copy number 6: 279; copy number 7: 129; copy number 8: 57; copy number 9: 41; copy number 10: 66; copy number 11: 13; copy number 12: 15; copy number 13: 3; copy number 14: 30; copy number 15: 11; copy number 16: 4; copy number 17: 17; copy number 18: 14; copy number 19: 27; copy number 20: 13; copy number 21: 19; copy number 22: 40; copy number 23: 14; copy number 24: 40; copy number 26: 6; copy number 29: 5; copy number 30: 2; copy number 32: 8; copy number 37: 26; copy number 49: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A3LS-01A-11D-A21P-01): tumor purity 0.41, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,043 genes in 78 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:7,951,263–8,611,924, 6 genes, copy number 6 (within-gene range 1–6): LMCD1-AS1, AC018832.1, AC023481.1, RNU4ATAC17P, LMCD1, AC034187.1.
- chr3:86,876,388–88,601,402, 22 genes, copy number 10 (within-gene range 1–10): VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5.
- chr3:90,030,284–91,513,775, 6 genes, copy number 8: U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2.
- chr4:137,425,426–137,603,430, 5 genes, copy number 5: STMN1P2, RPS23P2, PCDH18, LINC02172, AC116563.2.
- chr4:145,269,810–146,642,474, 28 genes, copy number 5: RPS23P4, LINC02266, RTN3P1, AC079228.1, AC093796.1, NMNAT1P4, SMAD1, SMAD1-AS2, SMAD1-AS1, MMAA, NCOA4P3, AC093864.1, C4orf51, ZNF827, AC104791.2, AC104791.1, Y_RNA, AC108206.1, LINC01095, LSM6, AC097372.2, REELD1, AC097372.3, AC097372.1, SLC10A7, MIR7849, RNU1-44P, POU4F2.
- chr5:403,731–2,184,820, 64 genes, copy number 7 (broad region; genes not listed).
- chr5:8,659,764–9,903,852, 24 genes, copy number 10 (within-gene range 2–10): AC091953.2, AC091953.6, AC091953.4, AC091932.4, AC091932.2, AC091932.1, AC091932.3, LINC02199, AC091895.1, AC021088.1, SEMA5A, MIR4636, AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221.
- chr5:20,606,710–21,779,522, 11 genes, copy number 11: LINC02146, LINC02241, AC138938.1, AC140168.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1.
- chr6:28,010,723–28,784,004, 45 genes, copy number 6: IQCB2P, ZSCAN16-AS1, U3, OR2W2P, OR2B7P, OR2B8P, OR1F12, AL121944.1, ZNF165, ZSCAN12P1, ZNF602P, ZSCAN16, AL358933.1, ZKSCAN8, ZNF192P1, AL022393.1, ZNF603P, ZNF192P2, TOB2P1, ZSCAN9, ZKSCAN4, NKAPL, ZSCAN26, AL021997.2, PGBD1, AL021997.1, SMIM15P2, ZSCAN31, ZKSCAN3, ZSCAN12, RNU2-45P, ZSCAN23, COX11P1, OR2E1P, Z98745.2, Z98745.1, GPX6, GPX5, ZBED9, AL049543.1, AL121932.1, AL121932.2, LINC00533, RPSAP2, NOP56P1.
- chr6:117,907,264–119,182,745, 13 genes, copy number 11–20 (within-gene range 3–20): SLC35F1, AL450405.1, AL589993.1, CEP85L, BRD7P3, PLN, Z99496.1, SSXP10, SELENOKP3, MCM9, ASF1A, AL137009.1, FAM184A.
- chr6:119,069,047–119,391,829, 6 genes, copy number 6–20: MIR548B, AL022722.2, MAN1A1, AL022722.1, RNU6-194P, AL078600.1.
- chr7:127,580,628–128,092,609, 10 genes, copy number 12: GCC1, ARF5, FSCN3, PAX4, AC073934.1, SND1, AC006529.1, SND1-IT1, LRRC4, MIR593.
- chr7:132,784,870–134,066,589, 8 genes, copy number 17–18 (within-gene range 2–18): CHCHD3, AC009365.3, AC008038.1, MIR3654, RNU6-92P, ST13P7, EXOC4, MIR6133.
- chr7:133,727,368–134,459,284, 8 genes, copy number 17: COX5BP3, RPS3AP27, LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1.
- chr8:38,142,700–38,996,824, 30 genes, copy number 5–14 (within-gene range 1–14): STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2.
- chr9:4,299,390–4,945,902, 17 genes, copy number 6: AL162419.1, RNU6-694P, SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1, AL353151.1, RCL1, KLF4P1, MIR101-2, AL158147.1, HNRNPA1P41.
- chr9:98,943,179–104,928,892, 89 genes, copy number 5–8 (broad region; genes not listed).
- chr9:137,459,952–137,870,016, 12 genes, copy number 5 (within-gene range 1–5): PNPLA7, MRPL41, DPH7, ZMYND19, ARRDC1, AL590627.2, ARRDC1-AS1, EHMT1, Metazoa_SRP, SETP5, AL590627.1, MIR602.
- chr12:49,556,544–49,708,165, 9 genes, copy number 10 (within-gene range 1–10): MCRS1, PRPF40B, AC020612.3, FAM186B, RNU6-834P, POLR2KP1, AC020612.1, HIGD1AP9, FMNL3.
- chr12:57,610,180–58,244,865, 37 genes, copy number 10–29: ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103.
- chr12:60,092,864–60,419,293, 6 genes, copy number 26: AC080011.1, AC087883.2, AC087883.1, Y_RNA, AC090022.1, AC090022.2.
- chr12:68,686,951–68,971,570, 12 genes, copy number 32–49: NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,400,903–69,855,363, 13 genes, copy number 22: RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2.
- chr12:71,125,085–72,186,618, 18 genes, copy number 6–30 (within-gene range 1–30): TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.
- chr12:74,537,835–75,390,928, 12 genes, copy number 23 (within-gene range 1–23): ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2.
- chr12:84,671,598–85,264,457, 5 genes, copy number 17 (within-gene range 2–17): AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1.
- chr12:89,010,681–90,112,779, 25 genes, copy number 5–23 (within-gene range 5–37): LINC02458, AC006199.1, RNU7-120P, MRPS6P4, DUSP6, AC024909.1, AC010201.3, AC010201.2, AC010201.1, POC1B, CENPCP1, POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P, BRWD1P2, LINC02399, AC126178.1.
- chr12:90,576,402–91,193,942, 11 genes, copy number 9–21: LINC02822, AC084365.1, AC112481.2, AC112481.1, CCER1, LINC00615, EPYC, KERA, LUM, DCN, AC007115.1.
- chr12:95,217,746–96,400,480, 34 genes, copy number 5–21 (within-gene range 1–21): VEZT, Y_RNA, CBX3P5, RNU6-808P, MIR331, MIR3685, AC084879.1, AC084879.2, RNU6-735P, AC018475.1, METAP2, USP44, PGAM1P5, Y_RNA, NTN4, AC090001.1, RNU6-247P, LINC02410, SNRPF, CCDC38, AC090001.2, AMDHD1, HAL, AC007298.2, LTA4H, AC007298.1, YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P.
- chr12:101,568,353–102,197,833, 24 genes, copy number 37: MYBPC1, AC117505.1, AC010205.1, CHPT1, RNY1P16, SYCP3, GNPTAB, RNU6-101P, AC063950.1, RNA5SP368, RNU6-172P, RNA5SP369, RNU6-1183P, HSPE1P4, DRAM1, AC084398.2, AC084398.1, AC079907.2, NENFP2, WASHC3, AC079907.1, NUP37, PARPBP, PMCH.
- chr12:105,173,297–106,058,254, 8 genes, copy number 9–21 (within-gene range 1–21): APPL2, C12orf75, AC078874.1, KCCAT198, AC079851.1, CASC18, ST13P3, AC011595.2.
- chr12:109,059,986–109,268,226, 5 genes, copy number 6 (within-gene range 1–6): RNA5SP372, ALKBH2, UNG, AC007637.1, ACACB.
- chr12:121,308,245–122,422,632, 39 genes, copy number 6–19 (within-gene range 1–19): ANAPC5, AC048337.1, RNF34, KDM2B, MIR7107, KDM2B-DT, RNU6-1004P, ORAI1, MORN3, AC084018.3, TMEM120B, RHOF, LINC01089, AC084018.1, AC084018.2, SETD1B, HPD, AC079360.1, AC069503.3, AC069503.5, PSMD9, AC069503.2, Metazoa_SRP, RNU7-170P, CFAP251, AC069503.1, BCL7A, AC156455.1, MLXIP, LRRC43, IL31, B3GNT4, AC048338.2, DIABLO, AC048338.1, VPS33A, CLIP1, RPL21P1, CLIP1-AS1.
- chr12:123,152,320–123,972,831, 35 genes, copy number 24 (within-gene range 1–24): MPHOSPH9, AC073857.1, C12orf65, CDK2AP1, AC068768.1, RNA5SP375, SBNO1, Y_RNA, SBNO1-AS1, MIR8072, KMT5A, RILPL2, COPS5P2, SNRNP35, RILPL1, AC145423.1, AC145423.2, MIR3908, TMED2-DT, TMED2, DDX55, SNORA9B, EIF2B1, GTF2H3, AC117503.3, AC117503.2, TCTN2, AC117503.1, ATP6V0A2, AC117503.5, RPL27P12, AC117503.4, DNAH10, CCDC92, DNAH10OS.
- chr12:124,993,645–125,662,377, 10 genes, copy number 7 (within-gene range 1–7): BRI3BP, THRIL, AC122688.1, AACS, AC122688.3, AC122688.2, AC122688.5, AC122688.4, TMEM132B, AC093028.1.
- chr19:38,374,536–38,769,904, 16 genes, copy number 9 (within-gene range 2–9): PSMD8, GGN, AC005789.1, SPRED3, FAM98C, RASGRP4, RYR1, AC067969.2, AC067969.1, MAP4K1, AC008649.1, EIF3K, ACTN4, AC008649.2, CAPN12, AC022144.1.
- chr20:31,257,664–31,801,805, 31 genes, copy number 7 (within-gene range 4–7): DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2.
- chr20:34,741,401–41,712,600, 179 genes, copy number 6–8 (within-gene range 2–8) (broad region; genes not listed).
- chr20:42,968,743–44,226,027, 31 genes, copy number 6–9: PTPRT-AS1, RN7SKP100, AL021395.1, RN7SL666P, PPIAP21, AL021395.2, AL031681.1, RNU6-743P, EIF4EBP2P1, Y_RNA, SRSF6, AL031681.2, RNU6-1251P, L3MBTL1, Z98752.2, Z98752.3, Z98752.1, SGK2, Z98752.4, IFT52, RPL27AP, MYBL2, GTSF1L, RNU6-639P, LINC01728, TOX2, RN7SL443P, JPH2, AL035447.1, OSER1, OSER1-DT.
- chr22:23,630,618–23,717,356, 6 genes, copy number 10 (within-gene range 1–10): AP000346.1, GUSBP11, AP000346.2, ASLP1, AP000347.1, RGL4.

Autosomal genes at a single copy (total copy number 1): 13,534. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
